Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A4F4, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A4F4-06A (Metastatic).

Patient: Xxxx

Translation of pathology report

Sample

1C D-0-3
Melanoma, NOS 8720/3
Site: Subcutaneous tissue, NOS C49.9
(pn T3S)
JW
10/7/12

Gross Pathology

Cryofixed specimen with a weight of 134 mg.

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 90 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine.

Eosinophilic nucleoli are present.

Some apoptotic cells are present.

There is a high nucleo/cytoplasmatic ratio. The mitotic count is 3 mitoses per square millimetre. The tumor cells have a middle sized pigmented cytoplasm.

The tumor shows a sheet like growth pattern.

Lymphocytic infiltrates compound approx. 5 percent of the tissue cells.

Melanophages are present.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

Source: NCI Genomic Data Commons file afd7f732-9357-400e-9355-a71e07e55328 (TCGA-FS-A4F4.8F51786F-405B-495A-B662-D0C17B68DC33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).